Somatic mutation profile of tumor specimen MP2PRT-PARMEG-TMP1-A (aliquot MP2PRT-PARMEG-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARMEG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.1 years (3,687 days).
Specimen MP2PRT-PARMEG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8abd76a7-d4d4-433b-a45d-0f68ec5e8776.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARMEG-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARMEG-NB1-B-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d7d3a75-2aa7-4dfe-ad01-81862650bbb1

The open-access MAF lists 30 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABTB1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 78/831 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773050003; called by muse, mutect2
- AL592490.1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 36/638 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69427551; called by muse, mutect2
- AMPH | c.396+1G>T p.X132_splice | Splice Site (SNP) | VAF 42/105 reads (40%) | catalogued as COSV100341576; called by muse, mutect2, varscan2
- AZGP1 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 44/330 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774688518; called by muse, mutect2, varscan2
- CAPN5 | c.883G>A p.A295T (on ENST00000456580; = p.A255T on NM_004055.5) | Missense Mutation (SNP) | VAF 58/1126 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.153); catalogued as rs782335833, COSV99582061; called by muse, mutect2
- CCNA1 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 188/482 reads (39%) | catalogued as rs267603811, COSV55220556; called by muse, mutect2, varscan2
- CILK1 | c.1853G>A p.R618Q (on ENST00000350082 / NM_001375397.1; = p.R611Q on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 243/534 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as COSV63154557; called by muse, mutect2, varscan2
- DDX50 | c.2159G>A p.R720Q | Missense Mutation (SNP) | VAF 242/592 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.885); catalogued as rs970465463, COSV65293059; called by muse, mutect2, varscan2
- ERC2 | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 253/576 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs746883356, COSV55657818; called by muse, mutect2, varscan2
- FAM234A | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 221/418 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.301); catalogued as rs757279121, COSV56993188; called by muse, mutect2, varscan2
- KCNB1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 127/294 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.142); catalogued as rs748573940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNN2 | c.76G>A p.E26K (on ENST00000264773; = p.E238K on NM_021614.4) | Missense Mutation (SNP) | VAF 78/1030 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.385); catalogued as COSV53289526; called by muse, mutect2
- MSLN | c.1504G>A p.V502M (on ENST00000382862 / NM_013404.4; = p.V494M on NM_005823.6) | Missense Mutation (SNP) | VAF 135/308 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs770060839; called by muse, varscan2
- MYO1B | c.3374G>A p.R1125Q (on ENST00000304164; = p.R1067Q on NM_012223.5) | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs766403785; called by muse, mutect2, varscan2
- PCDHAC1 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 227/487 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs781843995, COSV53836291; called by muse, mutect2, varscan2
- ZNF521 | c.53A>C p.K18T | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV64129816; called by muse, mutect2, varscan2
- ADCY10 | c.3975G>A p.M1325I | Missense Mutation (SNP) | VAF 30/373 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.164); called by muse, mutect2
- C12orf40 | c.1865G>A p.C622Y | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSTF2T | c.1752_1753insGC p.Q585Afs*3 | Frame Shift Ins (INS) | VAF 218/610 reads (36%) | called by mutect2, pindel, varscan2
- EPRS1 | c.1976C>G p.P659R | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IGKV2D-30 | chr2:89937679 TCCCACAGTGGTACAG>CCCA | Missense Mutation (DEL) | VAF 102/246 reads (41%) | called by pindel, varscan2*
- LLGL1 | c.2789C>A p.S930* | Nonsense Mutation (SNP) | VAF 74/448 reads (17%) | called by muse, mutect2, varscan2
- PLAU | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 86/662 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RYR2 | c.5365T>G p.S1789A | Missense Mutation (SNP) | VAF 81/524 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- WDR45 | c.770A>G p.D257G (on ENST00000376372 / NM_001029896.2; = p.D258G on NM_007075.3) | Missense Mutation (SNP) | VAF 307/746 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DLGAP1 | c.528G>A p.A176= | Silent (SNP) | VAF 439/946 reads (46%) | catalogued as rs775696302, COSV100228137; called by muse, mutect2, varscan2
- FAT1 | c.5844C>T p.Y1948= | Silent (SNP) | VAF 87/528 reads (16%) | catalogued as rs762561658, COSV71673406, COSV71676613; called by muse, mutect2, varscan2
- HMGXB4 | c.207G>A p.T69= | Silent (SNP) | VAF 26/346 reads (8%) | catalogued as rs781401005; called by muse, mutect2
- PCDHB15 | c.1809G>A p.S603= | Silent (SNP) | VAF 104/1044 reads (10%) | catalogued as rs782813959; called by muse, mutect2, varscan2
- KCNMA1 | c.2267-7494C>A | Intron (SNP) | VAF 96/252 reads (38%) | called by muse, mutect2, varscan2
